Surgical pathology report (de-identified scan), TCGA case TCGA-RP-A690, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RP-A690-06A (Metastatic).

Tumor ID

ICD-O-3
Melanoma malignant
8720/3
Date: Spinal cord
C72.0
JL 6/26/13

Microscopic Description:

Microscopic examination reveals a cellular neoplasm with considerable hemorrhage. The overall configuration is that of a spindle cell lesion with relatively uniform nuclei and occasional mitotic figures. Nucleoli are not prominent. Blood vessels appear intermixed uniformly throughout the lesion, some having prominent walls.

Addendum discussion:

The neoplastic cells are diffusely immunoreactive for both HMB-45 and S-100, consistent with melanocytic origin. They are negative for synaptophysin and GFAP. MIB-1 demonstrates scattered reactive cells with significant variability in proliferative activity in different tumor areas. In most areas, the labeling index would be about 1% and the highest area had a labeling index of 4.6%. In primary CNS melanocytic lesions, MIB-1 labeling indices >2% are more consistent with melanoma than melanocytoma.

Diagnosis:

Spinal Cord Tumor

Melanocytic lesion, consistent with melanoma.

Comment: This lesion does not demonstrate the mitotic activity that was seen in the previous biopsy. However, overall this tumor did demonstrate proliferative activity that is greater than that seen in melanocytoma. Also, the aggressive course based on the MRI findings are indicative of a malignant lesion.

Source: NCI Genomic Data Commons file a002e08c-e696-4e20-8b21-6ab0ae5d434c (TCGA-RP-A690.91AC7534-6DD2-4048-B217-0A0704C18339.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).